Somatic mutation profile of tumor specimen ALCH-B34L-TTP1-A (aliquot ALCH-B34L-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B34L, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 49.9 years (18,220 days).
Specimen ALCH-B34L-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3133fa67-9360-436e-8434-28cd1e1403da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B34L-NB1-A (Blood Derived Normal), aliquot ALCH-B34L-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c26e459-4eb0-4d6d-b9d1-98513fea8702

The open-access MAF lists 40 somatic variants for this specimen: 28 protein-altering or splice-affecting, 7 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 7, Intron 3, Frame Shift Del 2, Splice Site 1, Frame Shift Ins 1, Nonsense Mutation 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP32 | c.2686G>A p.G896R (on ENST00000310343 / NM_001378025.1; = p.G547R on NM_014715.4) | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1184380604; called by muse, mutect2, varscan2
- CDH5 | c.2107G>T p.G703W | Missense Mutation (SNP) | VAF 42/330 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100439253, COSV58517534; called by muse, mutect2, varscan2
- CRYBG1 | c.3098C>T p.A1033V | Missense Mutation (SNP) | VAF 48/313 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs1289631447; called by muse, mutect2, varscan2
- GOLM1 | c.871G>A p.G291R | Missense Mutation (SNP) | VAF 65/498 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs141196207; called by muse, mutect2, varscan2
- PCDHA13 | c.1607G>A p.S536N | Missense Mutation (SNP) | VAF 147/696 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.033); catalogued as COSV56527176; called by muse, mutect2, varscan2
- PLXNB3 | c.2663C>T p.S888L | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1557062131; called by muse, mutect2, varscan2
- PNPLA6 | c.1016A>G p.N339S (on ENST00000414982 / NM_001166111.2; = p.N291S on NM_006702.5) | Missense Mutation (SNP) | VAF 25/230 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.066); catalogued as rs1183371584; called by muse, mutect2, varscan2
- PRB3 | c.277C>A p.P93T | Missense Mutation (SNP) | VAF 18/265 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as COSV54388048; called by muse, mutect2
- TCHHL1 | c.1397G>A p.G466E | Missense Mutation (SNP) | VAF 38/204 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.1); catalogued as rs556122990, COSV64284845; called by muse, mutect2, varscan2
- TRAPPC1 | c.37G>T p.G13* | Nonsense Mutation (SNP) | VAF 33/283 reads (12%) | catalogued as COSV100366645; called by muse, mutect2, varscan2
- VCAN | c.4819C>A p.P1607T | Missense Mutation (SNP) | VAF 59/243 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs754532087; called by muse, mutect2, varscan2
- ADGRG4 | c.8108G>A p.G2703D | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- ARMCX5 | c.1439C>T p.A480V | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (1); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- ATP2A2 | c.2394_2395insAA p.D799Kfs*19 | Frame Shift Ins (INS) | VAF 76/577 reads (13%) | called by mutect2, pindel, varscan2
- BRWD3 | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- CACNG4 | c.498C>G p.D166E | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- DNAH8 | c.3065T>C p.V1022A | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.271); called by muse, mutect2
- EXOC6B | c.1343T>C p.I448T | Missense Mutation (SNP) | VAF 40/185 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- FGF23 | c.401del p.F134Sfs*16 | Frame Shift Del (DEL) | VAF 130/813 reads (16%) | called by mutect2, pindel, varscan2
- IRX4 | c.421G>C p.D141H | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- KIFAP3 | c.584C>T p.T195I | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- MECOM | c.319C>A p.Q107K (on ENST00000468789 / NM_001105078.4; = p.Q295K on NM_004991.4) | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- PKHD1 | c.6927G>C p.E2309D | Missense Mutation (SNP) | VAF 54/298 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- PMPCB | c.442A>C p.K148Q | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.009); called by muse, mutect2
- SLX4 | c.2477A>T p.E826V | Missense Mutation (SNP) | VAF 66/411 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- SPACA1 | c.731+1G>T p.X244_splice | Splice Site (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- ZNF469 | c.4317_4318delinsT p.L1440Sfs*87 (on ENST00000437464; = p.L1468Sfs*87 on NM_001367624.2) | Frame Shift Del (DEL) | VAF 34/275 reads (12%) | called by pindel, varscan2*
- ZNF850 | c.2824A>C p.K942Q | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- HPS5 | c.2193T>C p.S731= (on ENST00000349215 / NM_181507.2; = p.S617= on NM_007216.4) | Silent (SNP) | VAF 16/126 reads (13%) | called by muse, mutect2, varscan2
- ILK | c.1197G>A p.E399= | Silent (SNP) | VAF 20/416 reads (5%) | catalogued as rs1057522211, COSV54992595; ClinVar: likely benign; called by muse, mutect2
- MGAM | c.1176C>T p.N392= | Silent (SNP) | VAF 16/204 reads (8%) | called by muse, mutect2
- NOS3 | c.456G>A p.E152= | Silent (SNP) | VAF 43/290 reads (15%) | called by muse, mutect2, varscan2
- RPS6KA1 | c.456G>T p.R152= | Silent (SNP) | VAF 12/229 reads (5%) | called by muse, mutect2
- SYNE1 | c.13503C>G p.A4501= (on ENST00000367255 / NM_182961.4; = p.A4430= on NM_033071.3) | Silent (SNP) | VAF 24/356 reads (7%) | called by muse, mutect2
- ZNF33A | c.1416G>A p.E472= (on ENST00000458705 / NM_006974.3; = p.E473= on NM_006954.2) | Silent (SNP) | VAF 7/83 reads (8%) | called by muse, mutect2
- CCDC14 | c.373+198A>T | Intron (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- KIR3DX1 | n.533G>A | RNA (SNP) | VAF 16/412 reads (4%) | catalogued as rs757014625, COSV55598804; called by muse, mutect2
- NEDD4L | c.2427-12T>G | Intron (SNP) | VAF 19/228 reads (8%) | called by muse, mutect2
- POLA1 | chrX:24693942 G>T | 5'Flank (SNP) | VAF 10/146 reads (7%) | called by muse, mutect2
- TBCB | c.547+46C>T | Intron (SNP) | VAF 12/168 reads (7%) | catalogued as rs759953460; called by muse, mutect2
